Somatic mutation profile of tumor specimen MP2PRT-PAWAJH-TMP1-A (aliquot MP2PRT-PAWAJH-TMP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAWAJH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,016 days).
Specimen MP2PRT-PAWAJH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b90088f-b3d3-459b-8aa3-0b9f1ea69d1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWAJH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWAJH-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d898845a-67e7-4043-a56e-ac1b8c15920b

The open-access MAF lists 17 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Nonsense Mutation 3, Silent 2, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.5039_5041del p.S1680del | In Frame Del (DEL) | VAF 156/496 reads (31%) | hotspot (GDC flag); catalogued as rs587783502; called by pindel, varscan2
- PTPN11 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 61/425 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121918453, CM013418, CM090463, COSV61004775, COSV61004869, COSV61006317; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRB1 | c.1298C>T p.T433M | Missense Mutation (SNP) | VAF 108/500 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs764588354, COSV60102866; called by muse, varscan2
- DOCK1 | c.4928G>A p.R1643H | Missense Mutation (SNP) | VAF 54/364 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs776099873, COSV54733870, COSV54762409; called by muse, mutect2, varscan2
- FCAR | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 24/522 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs754594457, COSV100629139, COSV62031380; called by muse, mutect2
- GPR153 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 80/479 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs777967221, COSV64939081; called by muse, mutect2, varscan2
- MARCHF4 | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 13/424 reads (3%) | catalogued as COSV99814770; called by muse, mutect2
- PEPD | c.460A>G p.S154G | Missense Mutation (SNP) | VAF 20/392 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1283052512; called by muse, mutect2
- SALL4 | c.2578G>T p.A860S | Missense Mutation (SNP) | VAF 164/364 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.067); catalogued as COSV53849748; called by muse, mutect2, varscan2
- SPTLC3 | c.434C>A p.S145* | Nonsense Mutation (SNP) | VAF 70/227 reads (31%) | catalogued as COSV100983231, COSV65466906; called by muse, mutect2, varscan2
- AFDN | c.3367C>T p.R1123* | Nonsense Mutation (SNP) | VAF 44/319 reads (14%) | called by muse, mutect2, varscan2
- LRRC31 | c.455G>T p.C152F | Missense Mutation (SNP) | VAF 85/195 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RRAGA | c.625dup p.A209Gfs*21 | Frame Shift Ins (INS) | VAF 143/297 reads (48%) | called by mutect2, pindel, varscan2
- SCO1 | c.778C>G p.H260D | Missense Mutation (SNP) | VAF 31/382 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VSTM2B | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 74/497 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADAMTS5 | c.2724G>A p.K908= | Silent (SNP) | VAF 79/438 reads (18%) | catalogued as rs1469695928; called by muse, mutect2, varscan2
- SLC1A5 | c.1191C>T p.A397= | Silent (SNP) | VAF 34/338 reads (10%) | catalogued as rs779678004, COSV101314815; called by muse, mutect2, varscan2
